Somatic mutation profile of tumor specimen 0DJGE3 from CCDI case PBBVPL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, benign; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,126 days).
Specimen 0DJGE3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4de3476-3c44-4023-a86f-9a251dfeee21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJG6V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01f524fc-d62e-4a94-b454-2b76ab29323d

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1575G>C p.L525F (on ENST00000288602 / NM_001374244.1; = p.L485F on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 448/1451 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs180177036, CM060880, COSV56396779; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.4256A>T p.H1419L | Missense Mutation (SNP) | VAF 75/288 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV64725926; called by muse, mutect2, varscan2
- SI | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 96/2066 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52265455; called by muse, mutect2
- C2orf69 | c.775A>G p.T259A | Missense Mutation (SNP) | VAF 596/2154 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- PLAT | c.1675A>C p.N559H | Missense Mutation (SNP) | VAF 271/935 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADCY3 | c.387G>A p.L129= | Silent (SNP) | VAF 102/815 reads (13%) | catalogued as COSV53166466; called by muse, mutect2, varscan2
- PLEKHG5 | c.1437G>A p.E479= (on ENST00000400915 / NM_001042663.3; = p.E442= on NM_020631.6) | Silent (SNP) | VAF 178/547 reads (33%) | called by muse, mutect2, varscan2
- C1orf100 | c.57-32C>A | Intron (SNP) | VAF 77/205 reads (38%) | called by muse, mutect2, varscan2
- GPS2 | c.481-25G>A | Intron (SNP) | VAF 178/530 reads (34%) | called by muse, mutect2, varscan2
